Somatic mutation profile of tumor specimen TCGA-J4-A67K-01A (aliquot TCGA-J4-A67K-01A-21D-A30E-08) from TCGA case TCGA-J4-A67K, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 68.2 years (24,908 days).
Specimen TCGA-J4-A67K-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 879e3497-bf7f-4684-942a-59315bedd9f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J4-A67K-10A (Blood Derived Normal), aliquot TCGA-J4-A67K-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d979325-6cec-4874-8f57-5f4579c7c97c

The open-access MAF lists 27 somatic variants for this specimen: 21 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 5, Frame Shift Del 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOB | c.6838C>T p.H2280Y | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs913125435, COSV51933978; called by muse, mutect2, varscan2
- BNC2 | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66146162; called by muse, mutect2
- CERS2 | c.1019G>A p.R340H | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54981865; called by muse, mutect2, varscan2
- DPEP2 | c.735G>T p.K245N | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as COSV52054481; called by muse, mutect2, varscan2
- GDNF | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV58479294; called by muse, mutect2
- GUCY2C | c.1645G>C p.G549R | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367698688, COSV53786584, COSV53786766; called by muse, mutect2, varscan2
- HTR2B | c.76G>C p.V26L | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs764960723, COSV51449652, COSV51450465; called by muse, mutect2
- IL27RA | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as COSV54600480; called by mutect2, varscan2
- LIN28B | c.131G>T p.G44V | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100558653, COSV61494815; called by muse, mutect2, varscan2
- MUC17 | c.6212C>T p.S2071F | Missense Mutation (SNP) | VAF 83/304 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV60287369, COSV60299463; called by muse, mutect2, varscan2
- PKD1 | c.4034T>G p.V1345G | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51915487; called by muse, mutect2, varscan2
- PKDREJ | c.5564G>C p.G1855A | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV53548978; called by muse, mutect2, varscan2
- RNF13 | c.47A>G p.Y16C | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as COSV60130819; called by muse, mutect2, varscan2
- RSAD1 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.95); catalogued as rs747181180, COSV51955335, COSV51956718; called by muse, mutect2
- TIAM2 | c.4129C>A p.L1377I (on ENST00000529824; = p.L1348I on NM_012454.3) | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as COSV51637494; called by muse, mutect2, varscan2
- TRMO | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV63336671; called by muse, mutect2, varscan2
- VSTM2A | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs200451254, COSV56492709; called by muse, mutect2, varscan2
- ZNF614 | c.763A>G p.T255A | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1225965925, COSV54546017; called by muse, mutect2, varscan2
- BNC2 | c.1817del p.P606Rfs*7 | Frame Shift Del (DEL) | VAF 26/144 reads (18%) | called by mutect2, pindel, varscan2
- CHDH | c.1444del p.R482Efs*17 | Frame Shift Del (DEL) | VAF 13/111 reads (12%) | called by mutect2, pindel, varscan2
- LMAN2 | c.102del p.L35Ffs*8 | Frame Shift Del (DEL) | VAF 10/56 reads (18%) | called by mutect2, pindel, varscan2
- C6orf89 | c.882C>T p.L294= (on ENST00000373685; = p.L301= on NM_152734.4) | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as COSV62101789; called by muse, mutect2, varscan2
- DSG4 | c.1924C>T p.L642= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as rs1343699449, COSV57390056, COSV57391257; called by muse, mutect2, varscan2
- EVA1B | c.378G>A p.E126= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs753179253, COSV54634134; called by muse, mutect2, varscan2
- RIPK1 | c.1959C>T p.L653= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV52529271; called by muse, mutect2, varscan2
- ZNF99 | c.135C>T p.I45= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs147397251, COSV68055626; called by muse, mutect2, varscan2
- RGS3 | c.3081-343C>G | Intron (SNP) | VAF 34/258 reads (13%) | catalogued as COSV59515638; called by muse, mutect2, varscan2
